CCDI case PBBUCS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1aa8e26b-9593-41db-b734-ee60b87c2b62

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 0.2 years (70 days).

Biospecimens (3 samples)
- Sample 0DIYS2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIYS8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIYSE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
